Somatic mutation profile of tumor specimen TCGA-DD-A3A3-01A (aliquot TCGA-DD-A3A3-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.7 years (16,708 days).
Specimen TCGA-DD-A3A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a632e02-8146-4cb6-9306-b2f4b0ede2ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A3-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A3-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cea207f-7f1a-42fb-9bec-5b8b177ae0dc

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 36, Silent 18, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 79/212 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, varscan2
- STAT3 | c.1229A>G p.H410R | Missense Mutation (SNP) | VAF 74/140 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52885189; called by muse, mutect2, varscan2
- ALDH16A1 | c.2230T>C p.Y744H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99513211; called by muse, mutect2
- ATF6 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV63406512; called by muse, mutect2, varscan2
- CAPN9 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs151280259; called by muse, mutect2, varscan2
- CAPZA3 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV56850306; called by muse, mutect2, varscan2
- CATSPERG | c.2489A>T p.D830V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53047210; called by muse, mutect2, varscan2
- CEP350 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV62485718; called by muse, mutect2, varscan2
- CEP350 | c.3904G>A p.A1302T | Missense Mutation (SNP) | VAF 156/238 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1395107563, COSV62600006; called by muse, mutect2, varscan2
- DHODH | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV54661236, COSV54661506; called by muse, mutect2, varscan2
- DNAH8 | c.1488+1G>T p.X496_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as COSV59432416; called by muse, mutect2, varscan2
- DNASE2B | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV65743226; called by muse, mutect2, varscan2
- ELF4 | c.1868C>A p.S623Y | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV57451818; called by muse, mutect2, varscan2
- FREM2 | c.5305G>C p.A1769P | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54831789; called by muse, mutect2, varscan2
- GBP2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV65068710; called by muse, mutect2, varscan2
- HFM1 | c.2712G>T p.K904N | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54023671; called by muse, mutect2, varscan2
- KDR | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55760549; called by muse, mutect2, varscan2
- MUC20 | c.1483A>T p.T495S | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV57848358; called by muse, mutect2, varscan2
- NDST2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377733383; called by muse, mutect2, varscan2
- NIPBL | c.1164T>A p.N388K | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV56945887; called by muse, mutect2, varscan2
- OPRM1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs199984546, COSV100001175, COSV57674063; called by muse, mutect2, varscan2
- PCDHGA2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs370683887; called by muse, mutect2, varscan2
- PHACTR4 | c.1942G>T p.V648L (on ENST00000373839 / NM_001350159.2; = p.V658L on NM_023923.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1384154541, COSV65783406; called by muse, mutect2, varscan2
- PHLDB1 | c.2839C>A p.P947T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV61877079; called by muse, mutect2, varscan2
- PLA2R1 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51776357, COSV99323534; called by muse, mutect2, varscan2
- POLQ | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs773624174, COSV51747978; called by muse, mutect2, varscan2
- PRDX1 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV53113239; called by muse, varscan2
- PRKACA | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV58067103; called by muse, mutect2, varscan2
- PRUNE2 | c.3263A>C p.Y1088S | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as COSV65038965; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1184470612; called by muse, mutect2
- SF3B2 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV59427383; called by muse, mutect2, varscan2
- SLC34A2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs374467761, COSV65940968; called by muse, mutect2, varscan2
- SRPX | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 28/42 reads (67%) | catalogued as COSV59437616; called by muse, mutect2, varscan2
- STK3 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 16/223 reads (7%) | catalogued as rs755916185, COSV69222407; called by muse, mutect2
- TMEM177 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV55608305; called by muse, mutect2, varscan2
- TRAF3IP3 | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50551026; called by muse, mutect2, varscan2
- TRIM21 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54343131; called by muse, mutect2, varscan2
- TRMT44 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67663573; called by muse, mutect2, varscan2
- ZNF543 | c.1280A>C p.E427A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV58626752; called by muse, mutect2, varscan2
- BEST3 | c.1550del p.G517Afs*11 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- CCDC73 | c.2239dup p.T747Nfs*4 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- CWC27 | c.1277_1278dup p.E427Lfs*8 | Frame Shift Ins (INS) | VAF 130/277 reads (47%) | called by mutect2, pindel, varscan2
- FABP1 | c.274_276del p.V92del | In Frame Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- MEIOC | c.1454dup p.N485Kfs*2 | Frame Shift Ins (INS) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- NF1 | c.1440del p.K480Nfs*18 | Frame Shift Del (DEL) | VAF 91/220 reads (41%) | called by mutect2, pindel, varscan2
- POSTN | c.928del p.Q310Sfs*22 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- AC104389.6 | c.408G>A p.L136= | Silent (SNP) | VAF 68/215 reads (32%) | catalogued as COSV100400694, COSV57963223; called by muse, mutect2, varscan2
- AP5M1 | c.546T>C p.D182= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV55104791; called by muse, mutect2, varscan2
- C1orf21 | c.33T>A p.T11= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV52403218; called by muse, mutect2, varscan2
- CCN4 | c.510G>A p.P170= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs775016662, COSV51530348; called by muse, mutect2, varscan2
- DMXL1 | c.3081A>G p.P1027= | Silent (SNP) | VAF 66/250 reads (26%) | catalogued as rs1029381930, COSV60707150, COSV60718219; called by muse, mutect2, varscan2
- DOC2A | c.621G>A p.K207= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100451273, COSV58750880; called by muse, mutect2, varscan2
- DYNLL2 | c.219C>T p.F73= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV74093382; called by muse, mutect2, varscan2
- IL17RA | c.153G>A p.T51= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as rs767860569, COSV60051881; called by muse, mutect2, varscan2
- KIF2B | c.996G>T p.V332= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV52128066; called by muse, mutect2
- MAP2 | c.105C>A p.G35= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as COSV52284831; called by muse, mutect2, varscan2
- MPP6 | c.459A>G p.V153= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs548751295, COSV56036550; called by muse, mutect2, varscan2
- NOTCH3 | c.414C>T p.P138= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs759982965, COSV54629579; called by muse, mutect2, varscan2
- PRDM2 | c.4338G>A p.L1446= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV52444148; called by muse, mutect2, varscan2
- RUSC1 | c.2011C>T p.L671= (on ENST00000368352 / NM_001105203.2; = p.L202= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/71 reads (63%) | catalogued as rs1270149326, COSV52738745; called by muse, mutect2, varscan2
- SAMD9 | c.1467C>T p.P489= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV66073736; called by muse, mutect2, varscan2
- SPACA7 | c.120T>C p.S40= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV52098693; called by muse, mutect2
- SPATA5 | c.1839C>T p.A613= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV56773441; called by muse, mutect2, varscan2
- TBC1D13 | c.840G>T p.S280= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs373890081, COSV56353741; called by muse, mutect2, varscan2
